Somatic mutation profile of tumor specimen HCM-SANG-0272-C20-01B (aliquot HCM-SANG-0272-C20-01B-01D-A79M-36) from HCMI case HCM-SANG-0272-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-0272-C20-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ebb0865-e98a-453f-a919-fe48e1cf69d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0272-C20-10A (Blood Derived Normal), aliquot HCM-SANG-0272-C20-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b337fce9-06e8-415f-8cd9-27b9fe75fe71

The open-access MAF lists 98 somatic variants for this specimen: 75 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 20, Nonsense Mutation 5, Intron 3, Frame Shift Del 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARX | c.428_451del p.G143_A150del | In Frame Del (DEL) | VAF 98/194 reads (51%) | catalogued as rs387906493; ClinVar: uncertain significance / pathogenic; called by pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 56/288 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.537T>A p.H179Q | Missense Mutation (SNP) | VAF 113/315 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs876660821, CM0910925, COSV52669519, COSV52673406, COSV53016879; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.2690G>A p.R897Q | Missense Mutation (SNP) | VAF 102/285 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.595); catalogued as rs375519291; called by muse, mutect2, varscan2
- ACHE | c.1604C>T p.T535M | Missense Mutation (SNP) | VAF 125/604 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1430893148, COSV53815616; called by muse, mutect2, varscan2
- ADAMTS20 | c.5356G>T p.E1786* | Nonsense Mutation (SNP) | VAF 24/249 reads (10%) | catalogued as COSV67136501; called by muse, mutect2, varscan2
- CECR2 | c.3386C>T p.T1129M (on ENST00000342247 / NM_001290047.2; = p.T945M on NM_001290046.1) | Missense Mutation (SNP) | VAF 118/546 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs777432282, COSV52837111; called by muse, mutect2, varscan2
- CLNK | c.156A>C p.R52S | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV57018939; called by muse, mutect2, varscan2
- CNTN6 | c.861C>G p.F287L | Missense Mutation (SNP) | VAF 79/367 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.194); catalogued as rs866963872, COSV63169825; called by muse, mutect2, varscan2
- COL5A1 | c.2725C>T p.R909W | Missense Mutation (SNP) | VAF 104/385 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1257715072, COSV100880665; called by muse, mutect2, varscan2
- DYSF | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 79/315 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs755046419, COSV50629903; called by muse, mutect2, varscan2
- E2F7 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 61/310 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs762356959, COSV59737409; called by muse, mutect2, varscan2
- EYS | c.7205G>T p.R2402M | Missense Mutation (SNP) | VAF 36/246 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as CM104444; called by muse, mutect2, varscan2
- GRIN2A | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 132/539 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as rs758742694; called by muse, mutect2, varscan2
- IGLV3-16 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 28/370 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as rs1251907565; called by muse, mutect2
- MATN4 | c.1532C>T p.A511V (on ENST00000372754; = p.A470V on NM_003833.4) | Missense Mutation (SNP) | VAF 166/457 reads (36%) | PolyPhen benign (0.366); catalogued as rs771701454; called by muse, mutect2, varscan2
- MEGF8 | c.6016C>T p.R2006W (on ENST00000251268 / NM_001271938.2; = p.R1939W on NM_001410.3) | Missense Mutation (SNP) | VAF 115/389 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs762333959, COSV99238611; called by muse, mutect2, varscan2
- NEBL | c.515C>T p.T172M | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs548438161, COSV65799441; called by muse, mutect2, varscan2
- NLRX1 | c.1750C>T p.R584* | Nonsense Mutation (SNP) | VAF 27/462 reads (6%) | catalogued as rs776884246, COSV52703995; called by muse, mutect2
- OR2T2 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 40/363 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV61618302; called by muse, mutect2
- PLPP4 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 41/548 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as rs766256076, COSV64830002; called by muse, mutect2
- RASSF8 | c.463G>T p.V155L | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.054); catalogued as rs376924444; called by mutect2, varscan2
- RBM10 | c.1030G>A p.G344S | Missense Mutation (SNP) | VAF 118/486 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.243); catalogued as COSV61313291; called by muse, mutect2, varscan2
- RET | c.3233C>T p.T1078M | Missense Mutation (SNP) | VAF 59/328 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as rs762952212, COSV60703707; ClinVar: uncertain significance; called by muse, varscan2
- RIPK3 | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 89/292 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs753874743, COSV53474494; called by muse, mutect2, varscan2
- SALL1 | c.3082C>A p.P1028T | Missense Mutation (SNP) | VAF 32/358 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV51758244; called by muse, mutect2
- SSR1 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 115/407 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as rs747697031; called by muse, mutect2, varscan2
- STARD13 | c.686G>T p.S229I (on ENST00000336934 / NM_001243476.3; = p.S111I on NM_052851.3) | Missense Mutation (SNP) | VAF 115/630 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV55230010; called by muse, varscan2
- SYCE1L | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 25/266 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV101073319; called by muse, mutect2, varscan2
- TERF2 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 126/432 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as rs779198488; called by muse, mutect2, varscan2
- TNXB | c.7171G>A p.E2391K (on ENST00000647633; = p.E2144K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 167/692 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.047); catalogued as rs1413060979; called by muse, mutect2, varscan2
- TRIM3 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 117/546 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.095); catalogued as rs561735237, COSV61985571; called by muse, mutect2, varscan2
- WNT11 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 230/527 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1218682764, COSV59443089; called by muse, mutect2, varscan2
- ZNF790 | c.353G>C p.R118T | Missense Mutation (SNP) | VAF 94/327 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs745538231; called by muse, mutect2, varscan2
- ABHD11 | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 117/416 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- ADAM29 | c.2277T>A p.S759R | Missense Mutation (SNP) | VAF 79/411 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.164); called by mutect2, varscan2
- AGK | c.697A>G p.K233E | Missense Mutation (SNP) | VAF 56/287 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ANK2 | c.3433C>T p.R1145* | Nonsense Mutation (SNP) | VAF 83/304 reads (27%) | called by muse, mutect2, varscan2
- APC | c.4393_4394dup p.S1465Rfs*9 | Frame Shift Ins (INS) | VAF 67/232 reads (29%) | called by mutect2, varscan2
- ARHGAP12 | c.2444C>G p.P815R | Missense Mutation (SNP) | VAF 28/397 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BIRC6 | c.383T>G p.F128C | Missense Mutation (SNP) | VAF 66/255 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL20A1 | c.3184T>C p.S1062P | Missense Mutation (SNP) | VAF 46/394 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, varscan2
- DDX46 | c.1001A>C p.N334T | Missense Mutation (SNP) | VAF 57/268 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- DHX15 | c.720G>A p.M240I | Missense Mutation (SNP) | VAF 55/258 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM83B | c.1691C>G p.S564* | Nonsense Mutation (SNP) | VAF 115/424 reads (27%) | called by muse, mutect2, varscan2
- FAT3 | c.6225A>C p.E2075D | Missense Mutation (SNP) | VAF 73/417 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- FGFR2 | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 68/295 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FMO2 | c.679G>C p.D227H | Missense Mutation (SNP) | VAF 37/400 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.059); called by muse, mutect2
- ICE1 | c.5305C>G p.L1769V | Missense Mutation (SNP) | VAF 23/476 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- INSM2 | c.1007C>A p.S336* | Nonsense Mutation (SNP) | VAF 69/427 reads (16%) | called by muse, mutect2, varscan2
- KCNH1 | c.2491del p.C831Vfs*44 (on ENST00000271751 / NM_172362.3; = p.C804Vfs*44 on NM_002238.4) | Frame Shift Del (DEL) | VAF 97/468 reads (21%) | called by mutect2, pindel, varscan2
- KCNH3 | c.2517C>A p.F839L | Missense Mutation (SNP) | VAF 51/443 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- KIF18A | c.2495A>C p.K832T | Missense Mutation (SNP) | VAF 60/265 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LHB | c.193C>A p.L65M | Missense Mutation (SNP) | VAF 94/410 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MTFR2 | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 56/297 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- MUC16 | c.8642_8664del p.P2881Hfs*5 | Frame Shift Del (DEL) | VAF 57/246 reads (23%) | called by mutect2, pindel, varscan2
- NALCN | c.3874T>A p.F1292I | Missense Mutation (SNP) | VAF 53/307 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- NBEAL2 | c.968T>A p.L323Q | Missense Mutation (SNP) | VAF 93/304 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by mutect2, varscan2
- NFATC3 | c.1060A>C p.K354Q | Missense Mutation (SNP) | VAF 102/369 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- NIN | c.3089C>T p.S1030L | Missense Mutation (SNP) | VAF 16/354 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2
- NOTCH4 | c.1747G>A p.G583R | Missense Mutation (SNP) | VAF 111/402 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR13A1 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 19/599 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2
- OR2T35 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 42/300 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- PCDHB2 | c.841T>C p.Y281H | Missense Mutation (SNP) | VAF 23/403 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PHKA2 | c.3511G>T p.A1171S | Missense Mutation (SNP) | VAF 55/468 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- PLEKHG4 | c.1704G>C p.W568C | Missense Mutation (SNP) | VAF 20/383 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2
- RNF165 | c.571C>A p.P191T | Missense Mutation (SNP) | VAF 72/252 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by mutect2, varscan2
- SCNN1A | c.616G>T p.V206L | Missense Mutation (SNP) | VAF 56/674 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.014); called by muse, mutect2
- SLITRK2 | c.2429G>T p.C810F | Missense Mutation (SNP) | VAF 103/359 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRRM1 | c.877C>G p.P293A | Missense Mutation (SNP) | VAF 41/379 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- TGFBR1 | c.1498G>T p.G500C | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.022); called by muse, varscan2
- TPX2 | c.2097G>T p.Q699H | Missense Mutation (SNP) | VAF 128/375 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ZFP92 | c.1021G>T p.V341L | Missense Mutation (SNP) | VAF 197/551 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- ZNF121 | c.911A>C p.K304T | Missense Mutation (SNP) | VAF 89/394 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ZNF674 | c.1640A>C p.H547P | Missense Mutation (SNP) | VAF 95/463 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANO2 | c.2556C>T p.N852= (on ENST00000356134 / NM_001278597.3; = p.N856= on NM_001278596.3) | Silent (SNP) | VAF 24/376 reads (6%) | catalogued as rs773623058, COSV59035569; called by muse, mutect2
- CFAP58 | c.2613G>A p.T871= | Silent (SNP) | VAF 53/219 reads (24%) | catalogued as rs370337063; called by muse, mutect2, varscan2
- COL12A1 | c.2361A>G p.K787= | Silent (SNP) | VAF 42/478 reads (9%) | called by muse, mutect2
- CRYBG2 | c.2691C>G p.G897= | Silent (SNP) | VAF 130/574 reads (23%) | called by muse, mutect2, varscan2
- CYP2D7 | c.270G>A p.A90= | Silent (SNP) | VAF 78/976 reads (8%) | catalogued as rs1460805293; called by muse, mutect2
- DSCAM | c.4656C>T p.N1552= | Silent (SNP) | VAF 66/286 reads (23%) | called by muse, mutect2, varscan2
- ERVMER34-1 | c.384A>G p.E128= | Silent (SNP) | VAF 71/301 reads (24%) | called by muse, mutect2, varscan2
- FBXL6 | c.960C>G p.V320= | Silent (SNP) | VAF 204/485 reads (42%) | called by muse, mutect2, varscan2
- FHOD3 | c.1056C>T p.G352= | Silent (SNP) | VAF 87/285 reads (31%) | catalogued as rs142186343; called by muse, mutect2, varscan2
- MAP2 | c.4152C>T p.D1384= | Silent (SNP) | VAF 21/197 reads (11%) | catalogued as rs571107524, COSV52288764; called by muse, mutect2, varscan2
- OTOF | c.3276C>T p.F1092= (on ENST00000272371 / NM_194248.3; = p.F345= on NM_004802.4) | Silent (SNP) | VAF 30/253 reads (12%) | catalogued as rs776668692; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRR14 | c.1566A>G p.E522= | Silent (SNP) | VAF 134/514 reads (26%) | called by muse, varscan2
- PYROXD2 | c.16C>A p.R6= | Silent (SNP) | VAF 26/383 reads (7%) | called by muse, mutect2
- RTL9 | c.1113G>A p.A371= | Silent (SNP) | VAF 117/369 reads (32%) | catalogued as rs1474896375, COSV71825796, COSV71826158; called by muse, mutect2, varscan2
- SAP25 | c.426G>A p.E142= (on ENST00000538735; = p.E240= on NM_001168682.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 134/557 reads (24%) | called by muse, mutect2, varscan2
- SPEG | c.2394C>T p.N798= | Silent (SNP) | VAF 129/502 reads (26%) | catalogued as rs1356443986; called by muse, mutect2, varscan2
- SPHKAP | c.1770G>A p.P590= | Silent (SNP) | VAF 98/326 reads (30%) | catalogued as rs141688278; called by muse, mutect2, varscan2
- TESC | c.477C>T p.D159= | Silent (SNP) | VAF 111/401 reads (28%) | catalogued as rs572866908; called by muse, mutect2, varscan2
- TRIM69 | c.1320C>T p.L440= (on ENST00000329464 / NM_182985.5; = p.L281= on NM_080745.5) | Silent (SNP) | VAF 146/420 reads (35%) | catalogued as rs778145986; called by muse, mutect2, varscan2
- ZNF423 | c.2178G>T p.V726= (on ENST00000563137 / NM_001379286.1; = p.V718= on NM_015069.4) | Silent (SNP) | VAF 92/378 reads (24%) | called by muse, mutect2, varscan2
- ATXN8OS | n.499+1650A>G | Intron (SNP) | VAF 22/214 reads (10%) | called by muse, mutect2
- MOXD1 | c.265-12T>C | Intron (SNP) | VAF 40/388 reads (10%) | called by muse, mutect2
- TTN | c.10360+2523T>C | Intron (SNP) | VAF 68/265 reads (26%) | called by muse, mutect2, varscan2
